Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7379, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7379-01A (Primary Tumor).

[page 1 of 10]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1-11) SKIN, NERVE, TONGUE AND ORAL MUCOSA, VARIOUS SITES AS LISTED, BIOPSY: NEGATIVE FOR MALIGNANCY AT EACH SITE.

12) LYMPH NODES, LEVEL 1A, DISSECTION: TWO LYMPH NODES NEGATIVE FOR MALIGNANCY (0/2).

13) LYMPH NODES, LEVEL 2, DISSECTION: 10 LYMPH NODES NEGATIVE FOR MALIGNANCY (0/10).

14) LYMPH NODES, LEVEL 3, DISSECTION: 13 LYMPH NODES NEGATIVE FOR MALIGNANCY (0/13).

15) LYMPH NODES, LEVEL 4, DISSECTION: EIGHT LYMPH NODES NEGATIVE FOR MALIGNANCY (0/8).

16) TONGUE, JAW, FACIAL SKIN, BUCCAL MUCOSA, EXCISION: INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 4.2 CM IN GREATEST EXTENT, WITH INVASION INTO MANDIBLE; SURGICAL MARGINS NEGATIVE FOR MALIGNANCY, CLOSEST MARGIN POSTERIOR AND MEDIAL 0.3 CM; SUBMANDIBULAR GLAND WITH NO SIGNIFICANT HISTOPATHOLOGIC CHANGE; TWO LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA. (SEE COMMENT).

COMMENT: These findings correspond to AJCC stage p4a (pT4a,pN2,pMn/a)

.
. .
.

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Incisional and Excisional Biopsy, Resection

Note: Check 1 response unless otherwise indicated.

MACROSCOPIC

Specimen Type

☐ Incisional biopsy

☐ Excisional biopsy

☒ Resection (specify type): composite resection of tongue, jaw, neck, floor of mouth.

☐ Other (specify): _____

[page 2 of 10]
☐ Not specified

Tumor Site (check all that apply)

- ☐ Lip
- ☒ Oral cavity
- ☐ Pharynx, oropharynx
- ☐ Pharynx, hypopharynx
- ☐ Pharynx, nasopharynx
- ☐ Larynx, supraglottis
- ☐ Larynx, glottis
- ☐ Larynx, subglottis
- ☐ Paranasal sinus(es), maxillary
- ☐ Paranasal sinus(es), ethmoid
- ☐ Other (specify): _____
- ☐ Not specified

Tumor Size

Greatest dimension: 4.5 cm

*Additional dimensions: 3.5 x 0.8 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

Carcinomas of the Upper Aerodigestive Tract

☒ Squamous cell carcinoma, conventional

Squamous Cell Carcinoma, Variant

- ☐ Verrucous carcinoma
- ☐ Spindle cell squamous carcinoma
- ☐ Adenosquamous carcinoma
- ☐ Basaloid squamous cell carcinoma
- ☐ Papillary squamous cell carcinoma
- ☐ Lymphoepithelioma-like carcinoma (non-nasopharyngeal)

Sinonasal Carcinoma

- ☐ Keratinizing sinonasal carcinoma
- ☐ Non-keratinizing sinonasal carcinoma (Transitional type)
- ☐ Sinonasal undifferentiated carcinoma (SNUC)

Nasopharyngeal Carcinoma

- ☐ Keratinizing nasopharyngeal carcinoma
- ☐ Non-keratinizing nasopharyngeal carcinoma
- ☐ Non-keratinizing nasopharyngeal carcinoma, differentiated
- ☐ Non-keratinizing nasopharyngeal carcinoma, undifferentiated (lymphoepithelioma)
- ☐ Non-keratinizing nasopharyngeal carcinoma, mixed differentiated and undifferentiated

☐ Adenocarcinoma, salivary gland type (specify type):

[page 3 of 10]
Adenocarcinoma, Non-salivary Gland Type

- ☐ Papillary adenocarcinoma
- ☐ Intestinal-type adenocarcinoma
- ☐ Adenocarcinoma not otherwise specified (NOS), low grade
- ☐ Adenocarcinoma NOS, intermediate grade
- ☐ Adenocarcinoma NOS, high grade

Neuroendocrine carcinoma

- ☐ Typical carcinoid tumor (well differentiated neuroendocrine carcinoma)
- ☐ Atypical carcinoid tumor (moderately differentiated neuroendocrine carcinoma)
- ☐ Small cell carcinoma (poorly differentiated neuroendocrine carcinoma)
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ G1: Well differentiated
- ☒ G2: Moderately differentiated
- ☐ G3: Poorly differentiated
- ☐ Other (specify): _____

Pathologic Staging (pTNM) (see appropriate site below)

Note: The phrases in *italics* include clinical findings required for AJCC staging. This clinical information may be unknown to the pathologist. It is included here only for the sake of completeness.

Primary Tumor (pT): Oropharynx

- ☐ pTX: Cannot be assessed
- ☐ pT0: No evidence of primary tumor
- ☐ pTis: Carcinoma in situ
- ☐ pT1: Tumor 2 cm or less in greatest dimension
- ☐ pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
- ☐ pT3: Tumor more than 4 cm in greatest dimension
- ☒ pT4a: Tumor invades larynx, deep/extrinsic muscle of tongue, medial pterygoid muscles, hard palate, or mandible
- ☐ pT4b: Tumor invades lateral pterygoid muscle, pterygoid plates, lateral nasopharynx, or skull base, or encases carotid artery

Regional Lymph Nodes (pN): All Aerodigestive Sites Except Nasopharynx

- ☐ pNX: Cannot be assessed
- ☐ pN0: No regional lymph node metastasis
- ☐ pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension
- ☐ pN2a: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension
- ☒ pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension
- ☐ pN2c: Metastasis in bilateral or contralateral lymph nodes, none

[page 4 of 10]
more than 6 cm in greatest dimension

___ pN3: Metastasis in a lymph node more than 6 cm in greatest dimension

Specify: Number examined: 35

Number involved: 2

*Extra-capsular Extension of Nodal Tumor

* ☒ Absent

* ___ Present

* ___ Indeterminate

Distant Metastasis (pM)

☒ pMX: Cannot be assessed

___ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

___ Cannot be assessed

☒ Margins uninvolved by tumor

Distance of tumor from closest margin: 3 mm

Specify margin, if possible: posterior and medial

☒ Carcinoma in situ absent

___ Carcinoma in situ present

___ Carcinoma in situ, not applicable

___ Margin(s) involved by tumor

Specify margins(s), if possible: _____

___ Not applicable

*Venous/Lymphatic (Large/Small Vessel) Invasion (V/L)

* ☒ Absent

* ___ Present

* ___ Indeterminate

Perineural Invasion

☒ Absent

___ Present

*Additional Pathologic Findings (check all that apply)

* ___ None identified

* ___ Carcinoma in situ

* ___ Inflammation (specify type): _____

* ___ Epithelial hyperplasia

* ___ Epithelial dysplasia

* ___ Other (specify): _____

*Comment(s)

Data elements with asterisks are not required for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management.

Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen

Electronically Signed Out by [REDACTED].

[page 5 of 10]
CLINICAL DATA

Clinical Features: received on towel with orientation to superior

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) anterior inferior skin margin, 2) anterior superior skin margin, 3) posterior inferior skin margin, 4) posterior superior skin margin, 5) lingual nerve, 6) floor of mouth, mucosal margin, 7) ventral tongue, mucosal margin, 8) retromolar trigone mucosal margin, 9) soft palate mucosal margin, 10) buccal mucosal margin, 11) lip mucosa margin, 12) level A1 neck dissection, 13) left neck level 2, 14) left neck level 3, 15) left neck level 4, 16) tongue, jaw, level 1B, facial skin and mucosal margin

INSTRUCTIONS TO PATHOLOGIST: High risk HPV ISH and P16 IHC on permanent section.

GROSS DESCRIPTION:

1) SOURCE: Anterior Inferior Skin Margin

Received fresh in a container labeled with the patient's name is a single portion of skin measuring 7.0 x 0.1 cm and excised to a depth of 0.3 cm. The specimen is entirely submitted for frozen section diagnosis, following inking for orientation: blue at superior or black at inferior. Summary of sections: 1AFSC, 1/1.

2) SOURCE: Anterior Superior Skin Margin

Received fresh in a container labeled with the patient's name is a single portion of skin measuring 5.0 x 0.1 cm and excised to a depth of 0.2 cm. The specimen is entirely submitted for frozen section diagnosis, following inking for orientation: blue at superior or black at inferior. Summary of sections: 2AFSC, 1/1.

3) SOURCE: Posterior Inferior Skin Margin

Received fresh in a container labeled with the patient's name is a single portion of skin measuring 4.6 x 0.2 cm and excised to a depth of 0.3 cm. The specimen is entirely submitted for frozen section diagnosis, following inking for orientation: blue at superior or black at inferior. Summary of sections: 3AFSC, 1/1.

[page 6 of 10]
4) SOURCE: Posterior Superior Skin Margin

Received fresh in a container labeled with the patient's name is a single portion of skin measuring 5.2 x 0.2 cm and excised to a depth of 0.3 cm. The specimen is entirely submitted for frozen section diagnosis, following inking for orientation: blue at superior or black at inferior. Summary of sections: 4AFSC, 1/1.

5) SOURCE: Lingual Nerve

The specimen labeled "lingual nerve" is received fresh for intraoperative consultation and consists of a 0.2 x 0.2 x 0.1 cm segment of flat, tan to yellow tissue. The specimen is submitted en entirety for frozen section analysis. Summary of sections: 5AFSC, lingual nerve, 1/1.

6) SOURCE: Floor of Mouth Mucosal Margin

The specimen labeled "floor of mouth mucosal margin" is received fresh for intraoperative consultation and consists of a flat segment of tan to red tissue measuring 2.6 x 0.3 x 0.1 cm segment. The sample is received with a mark denoting the inferior portion of the sample. This area is marked in black. The sample is received on a cloth towel. The specimen is submitted in entirety for frozen section analysis. Summary of sections: 6AFSC, 1/1.

7) SOURCE: Ventral Tongue Mucosal Margin

The specimen labeled "ventral tongue mucosal margin" is received fresh for intraoperative consultation on a cloth towel and consists of a flat, tan segment of tissue measuring 3.5 x 0.2 x 0.2 cm segment. The specimen is received with a mark denoting the inferior portion of the sample. This area is inked black. The specimen is submitted in entirety for frozen section analysis. A portion of the specimen was destroyed during frozen section processing. The remainder of the specimen is submitted for permanent section. Summary of sections: 7AFSC, 1/1.

8) SOURCE: Retromolar Trigone Mucosal Margin

The specimen labeled "retromolar trigone mucosal margin" is received fresh for intraoperative consultation and consists of a flat tan segment of tissue measuring 0.7 x 0.3 x 0.2 cm. The specimen is received on a cloth towel. The sample is received with a mark denoting the inferior aspect. This portion of the specimen is inked in black. The sample is submitted in entirety for frozen section analysis. Summary of sections: 8AFSC, retromolar trigone mucosal margin, 1/1.

9) SOURCE: Soft Palate Mucosal Margin

The specimen labeled "soft palate mucosal margin" is received fresh for intraoperative consultation on a cloth towel and consists of a flat section of tan to pink tissue measuring 1.8 x 0.2 x 0.1 cm. The specimen is received with a mark denoting the inferior aspect of the specimen; this portion is inked in blue. The specimen is submitted in entirety for frozen

[page 7 of 10]
section analysis.Summary of sections: 9AFSC, soft palate mucosal margin, 1/1.

10) SOURCE: Buccal Mucosal Margin

The specimen labeled "buccal mucosal margin" is received fresh for intraoperative consultation on a cloth towel. The specimen measures 5.7 x 0.3 x 0.2 cm segment. The sample is received with a mark denoting the inferior portion of the sample; this portion of the specimen is inked in blue. The specimen is submitted in entirety for frozen section analysis.Summary of sections: 10AFSC, 1/1.

11) SOURCE: Lip Mucosal Margin

The specimen labeled "lip mucosal margin" is received fresh on a cloth towel and consists of a segment of tan flat tissue measuring 3.8 x 0.2 x 0.2 cm segment. The sample is received with a mark denoting the inferior aspect of the sample; this area is inked in blue. The opposite end of the specimen has a focal black discoloration. The specimen is submitted in entirety for frozen section analysis.Summary of sections: 11AFSC, lip mucosa margin, 2/1 (sample separated during frozen section processing).

12) SOURCE: Level 1A Neck Dissection

The specimen labeled "level 1A neck dissection" is received fresh and consists of a 2.2 x 1.2 x 0.8 cm portion of lobulated fibroadipose tissue with two palpable lymph node candidates. The first is removed from the specimen that measures 0.2 x 0.2 x 0.2 cm. A second larger candidate lymph node is palpated measuring 1.1 x 0.6 x 0.2 cm. The remainder of the specimen is lobulated fibroadipose tissue. The specimen is submitted in entirety.Summary of sections: 12A, small candidate lymph node, 1; 12B, larger candidate lymph node #1, 1/1; 12C, remainder of tissue, 3/1.

13) SOURCE: Left Neck Level 2

The specimen labeled "left neck level 2" is received fresh and consists of a segment of lobulated fibroadipose tissue with candidate lymph nodes measuring 5.5 x 4.7 x 0.3 cm. The sample is examined revealing multiple candidate lymph nodes, the largest of which measures 3.1 x 1.1 x 0.6 cm. All candidate lymph nodes are submitted in entirety.Summary of sections: 13A, four distinct candidate lymph nodes, 4/1; 13B, two distinct candidate lymph nodes, 2/1; 13C-13D, sections of largest candidate lymph node, 13C, 4/1, 13D, 3/1; 13E, additional candidate lymph nodes (two) with representative sections of lobulated fibroadipose tissue.

14) SOURCE: Left Neck Level 3

The specimen labeled "left neck level 3" is received fresh and consists of a segment of lobulated fibroadipose tissue with candidate lymph nodes measuring 6.3 x 4.3 x 0.3 cm. Numerous small candidate lymph nodes are identified, the largest of which measures 0.7 x 0.4 x 0.2. The majority of the specimen is submitted.Summary of sections: 14A-14C, candidate lymph nodes, 4/1 each; 14D, candidate lymph nodes with fibroadipose tissue, 4/1; 14E, representative section of fibroadipose tissue with possible lymph

[page 8 of 10]
nodes, 1/1.

15) SOURCE: Left Neck Level 4

The specimen labeled "left neck level 4" is received fresh and consists of a 6.0 x 4.5 x 0.3 cm segment of lobulated fibroadipose tissue with candidate lymph nodes. The largest identifiable candidate lymph node is 1.0 x 0.5 x 0.3 cm. Only one distinct candidate lymph node is identified. The specimen is submitted in entirety. Summary of sections: 15A, candidate lymph nodes, 3/1; 15B-E, remainder of tissue, 15B, 2/1, 15C, 1/1, 15D, 2/1, 15E, 3/1.

16) SOURCE: Tongue, Jaw, Level 1B, Facial Skin and Buccal Mucosa

The specimen labeled "tongue, jaw, level 1B facial skin and buccal mucosa" is received fresh and consists of an 8.0 cm from anterior to posterior, 7.0 cm from superior to inferior and 5.0 cm from medial to lateral resection including mandible, skin, salivary gland and buccal mucosa. Within the buccal mucosa, there is an ill-defined necrotic, red-tan ulcerating mass, 4.2 x 3.5 x 0.8 cm. Along the superficial surface of the specimen, there is an attached 6.5 x 5.5 cm roughly ovoid excision of tan wrinkled skin. The specimen is marked with inked as follows: anterior-orange; posterior-black; medial-red; lateral-blue; superior-yellow; and inferior-green. The specimen is serially sectioned revealing the lesion to extend through the mandible towards the anterior skin surface, with a maximum of the tumor 2.8 cm. The lesion extends into the dermis and is 0.3 cm from the skin surface. Within the inferior aspect of the mandible, just overlying the salivary gland, there is a 1.8 cm in greatest dimension grossly positive lymph node candidate. Sectioning through the salivary gland reveals a normal lobulated surface with no discrete, grossly suspicious lesions identified. The lesion also extends into the muscular tissue and lies 0.5 cm from the red medial margin. The lesion is 0.7 cm from the anterior margin, 0.9 cm from the posterior margin, 1.2 cm from the blue inked lateral margin and greater than 3.0 cm from the nearest green inferior margin. No additional lymph node candidates are identified. Representative sections are submitted. A portion of tumor is submitted [REDACTED] and placed in glutaraldehyde and within the -80 freezer on hold for possible future studies.

Summary of sections: 16A, buccal mucosa and lesion upon approach to superior and anterior margins, 1/1; 16B, lesion and muscular tissue upon approach to medial and posterior margins, 2/1; 16C, nearest superior margin, 1/1; 16D, nearest medial margin, 2/1; 16E, salivary gland and portion of lymph node candidate, 1/1; 16F, skin upon approach to blue inked lateral margin, 1/1; 16G, skin and lesion upon approach to posterior margin, 1/1; 16H, lesion and skin upon approach to anterior margin, 1/1; 16I, lesion and vessel mucosa upon approach to superior margin, 1/1; 16J, lesion with posterior and superior margin, 1/1; 16K, positive lymph node candidate and salivary gland, 1/1; 16L, additional section of medial margin with lesion, 1/1; 16M, 16M, mandible with surrounding lesion, 1/1 each; 16O, anterior bone margin, 1/1; 16P, posterior bone margin, bisected, 2/1.

Dictated by [REDACTED],
[REDACTED] 4.

[page 9 of 10]
Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Anterior Inferior Skin Margin

FROZEN SECTION DIAGNOSIS: DYSPLASIA, NEGATIVE FOR TUMOR. [REDACTED]

2) SOURCE: Anterior Superior Skin Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

3) SOURCE: Posterior Inferior Skin Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

4) SOURCE: Posterior Superior Skin Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

5) SOURCE: Lingual Nerve

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

6) SOURCE: Floor of Mouth Mucosal Margin

FROZEN SECTION DIAGNOSIS: KERATOSIS AS DISCUSSED, NEGATIVE FOR HIGH GRADE DYSPLASIA. [REDACTED]

7) SOURCE: Ventral Tongue Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] J

8) SOURCE: Retromolar Trigone Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

9) SOURCE: Soft Palate Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

10) SOURCE: Buccal Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

11) SOURCE: Lip Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

[page 10 of 10]
Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xDECALCIFICATION

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA [REDACTED]) as qualified to perform high complexity clinical laboratory testing.

ADDENDUM FINDINGS:

HPV analysis as performed by [REDACTED] Reference Laboratories shows the tumor to be P16 negative by immunohistochemistry and HPV-16 negative by in-situ hybridization.

[REDACTED]

Electronically signed by [REDACTED].

Slides and report reviewed by Attending Pathologist

[REDACTED]

Source: NCI Genomic Data Commons file 331f532c-fa3a-4cd8-ad52-48b2c3f57939 (TCGA-CR-7379.A4B27CC0-2AFE-40CE-9B5B-FEDC84A4457F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).